Surgical pathology report (de-identified scan), TCGA case TCGA-CN-5365, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-5365-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Report Type rt
Date of Event
Sex
Authored by
Hosp/Group

PATIENT HISTORY:

Squamous cell carcinoma of right tonsil.

PRE-OP DIAGNOSIS: None given.

POST-OP DIAGNOSIS: Same.

C RE: Tonsillectomy and right neck dissection.

FINAL DIAGNOSIS:

PART 1, 2, 3, 4, AND 5. TONSIL, RIGHT, BASE OF TONGUE, RIGHT SOFT PALATE, LATERAL AND MEDIAL PHARYNGEAL, TONSILLECTOMY WITH MARGINAL BIOPSIES-

A. INVASIVE SQUAMOUS CELL CARCINOMA (3.7 CM), KERATINIZING, MODERATELY DIFFERENTIATED.

B. ANGIOLYMPHATIC INVASION PRESENT.

C. NO PERINEURAL INVASION PRESENT.

D. ALL SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.

E. PATHOLOGIC STAGE: pT2N3MX

PART 6. LYMPH NODES, RIGHT, LEVEL I-IV, NECK DISSECTION-

A. METASTATIC SQUAMOUS CELL CARCINOMA IN AT LEAST ONE OF FOUR LYMPH NODES (1/4).

1. POSITIVE NODE (6.5 CM) WITH EPICENTER IN LEVEL II (see comment).

2. EXTRACAPSULAR EXTENSION PRESENT.

B. UNREMARKABLE SUBMANDIBULAR GLAND.

PART 7. LYMPH NODES, RIGHT, LEVEL V, NECK DISSECTION-

E LYMPH NODES, NO TUMOR PRESENT (0/5).

The positive node likely represents a mass of matted lymph nodes, but for staging purposes we have considered it a single node.

My signification that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in seven parts.

Part 1 is labeled with the patient's name, initials xx, medical record number and "base of tongue." The specimen consists of a 0.8-cm in largest dimension fragment of soft tissue covering by gray-pink, soft mucosa. Intraoperative consultation was requested for part 1 and was performed. Part 1 is entirely submitted in cassette 1A.

Part 2 is labeled with the patient's name, initials xx, medical record number and "right soft palate." Part 2 consists of a 1.5 cm in largest diameter fragment of soft tissue, inked blue. Part 2 is entirely submitted in cassette

[page 2 of 4]
2A.

Part 3 is labeled with the patient's name, initials xx, medical record number and "lateral pharyngeal." Part 3 consists of a 0.8 cm in largest diameter fragment of soft tissue. Part 3 is entirely submitted in cassette 3A.

Part 4 is labeled with the patient's name, initials xx, medical record number and "medial pharyngeal" and consists of a 0.9 cm in largest dimension fragment

of soft-to-rubbery tissue. Part 4 is entirely submitted in cassette 4A.

Part 5 is labeled with the patient's name, initials xx, medical record number and "right tonsils, suture medial" and consists of a 5.5 x 4.0 x 3.5 cm fragment of soft tissue with an exophytic solid gray mass, 3.7 x 3.5 x 2.3 cm in largest dimension. The mass is 0.3 cm from the deep margin and is inked black. Digital images are taken. A portion is submitted for tumor bank. Representative sections of the tumor in its relationship to the deep margin are submitted in cassettes 5A-5E.

Part 6 is labeled with the patient's name, initials xx, medical record number and "right neck levels 1-4." Part 6 consists of a fragment of fibroadipose tissue, 9.0 x 6.5 x 4.0 cm in largest dimension. The specimen is distorted by a 6.5 cm in largest dimension mass, which is lobulated, encapsulated and has a

yellow fragile necrotic-appearing cut section surface. Digital images are taken. The mass is located at level 4. The remainder of the specimen contains an unremarkable lobulated major salivary gland tissue, 3.0 cm in largest dimension. Several level 3 lymph nodes are identified. The largest level 3 lymph node measures 0.8 cm in largest dimension. Representative sections are submitted as follows:

6A-6F - representative sections of the large mass with capsule

6G - three lymph nodes, two lymph nodes (largest) are bisected

6H - representative section of major salivary gland (submandibular).

Part 7 is labeled with the patient's name, initials [REDACTED], medical record number and "right neck level 5" and consists of a 2.5 cm in largest diameter fragment

of yellow, lobulated fibroadipose tissue with potential lymph node, up to 0.5 largest dimension.

[REDACTED]
[REDACTED] VE CONSULTATION:

PART 1AFS: BASE OF TONGUE, BIOPSY

A. BENIGN.

B. NO TUMOR SEEN ([REDACTED]).

PART 2AFS: RIGHT SOFT

A. BENIGN.

[REDACTED] NINKED, SPECIMEN 2 IS BLUE) ([REDACTED])

[REDACTED]
[REDACTED] L, BIOPSY

A. BENIGN.

B. NO TUMOR SEEN ([REDACTED]).

PART 4AFS: MEDIAL PHARY

A. BENIGN.

B. NO TUMOR SEEN (PART 3 IS UNINKED, PART 4 IS BLUE) [REDACTED]

[REDACTED]
[REDACTED] OPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu

[page 3 of 4]
Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The [REDACTED] d its performance characteristics determined by the [REDACTED], Department of Pathology, as required by the C A [REDACTED]

[REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND MINOR SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: Tonsillectomy

TUMOR SITE: Pharynx, oropharynx

TUMOR SIZE: Greatest dimension: 3.7 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PATHOLOGIC STAGING (pTNM): pT2

pN3

Number of nasopharynx regional lymph nodes examined: 9

Number of nasopharynx regional lymph nodes involved: 1

Extra-capsular extension of nodal tumor: Present

pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION: Absent

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: biopsy

Taken: [REDACTED] Received: [REDACTED]

Stain/c

FRZ Single x 1 A

H&E x 1 A

H&E x 1 A

Part 2: ate

Taken: [REDACTED] Received: [REDACTED]

Stain/c

FRZ Single x 1 A

H&E x 1 A

Part 3: geal

Taken: [REDACTED] Received: [REDACTED]

Stain/cn

FRZ Single x 1 A

H&E x 1 A

Part 4: al

Taken: [REDACTED] Received: [REDACTED]

Stain/cn

FRZ Single x 1 A

H&E x 1 A

Part 5:

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

[page 4 of 4]
H&E x 1 E
PHSU x 2 (none)
Part 6: el 1-4
Taken: [REDACTED] Received: [REDACTED]
Stain/c
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
PHSU x 1 (none)
Part 7: el 5
Taken: [REDACTED] Received: [REDACTED]
Stain/c
x 1 A
[REDACTED]

Source: NCI Genomic Data Commons file 1b3596c8-d96b-409e-844d-9d9d6ee2131a (TCGA-CN-5365.3A9A2025-BEF4-409A-AF96-ADFC08DB6B1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).